Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5720, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5720-01A (Primary Tumor).

Diagnosis(es):

Total gastrectomy specimen including an extensively ulcerated, weakly to largely dedifferentiated gastric adenocarcinoma of maximum diameter 6.5 cm in the area of the cardia directly beneath the Z line with infiltration of the perimuscular fatty tissue and evidence of carcinomatous lymphangitis. Tumor-free regional lymph nodes. Free-free oral resection margin lined with typical squamous epithelium and aboral resection margin lined with typical duodenal mucosa. Free-free omental fatty tissue.

Free stage: pT2b pN0 (0/60) pMX;

Source: NCI Genomic Data Commons file 1bf23f02-f17b-4be8-ac79-89c01144af0e (TCGA-CG-5720.710FA5DF-872B-436B-8A70-83776B199E3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).